TCGA case TCGA-50-5946 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c95957a7-1a1a-4c8d-bb61-7c99b500f224

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (3)
1. Adenocarcinoma with mixed subtypes (the primary disease): ICD-O-3 morphology code: 8255/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 62.6 years (22,852 days); Year of diagnosis: 2010; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Adenocarcinoma with mixed subtypes). Age at diagnosis: 63.2 years (23,073 days); Days to diagnosis: 221 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 221 days; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS to Locoregional Site.
3. Metastasis of diagnosis 1 (Adenocarcinoma with mixed subtypes). Age at diagnosis: 64.8 years (23,663 days); Days to diagnosis: 811 days (2.2 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (5 entries)
- Day 221 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 221 days; Evidence of progression type: Biopsy with Histologic Confirmation.
- Days to follow up: 349 days; Disease response: With Tumor.
- Days to follow up: 686 days (1.9 years); Disease response: With Tumor.
- Day 811 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 811 days (2.2 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 1,617 days (4.4 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking quit year: 2009.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-50-5946-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 1.2; Shortest dimension: 0.3.
  Slide TCGA-50-5946-01A-01-TS1: Section location: Top; Percent tumor cells: 73; Percent tumor nuclei: 80; Percent normal cells: 19; Percent necrosis: 8; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 1.
  Slide TCGA-50-5946-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 1.
- Sample TCGA-50-5946-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-50-5946-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Longest dimension: 1.9; Intermediate dimension: 0.4; Shortest dimension: 0.2.
  Slide TCGA-50-5946-02A-01-BS1: Section location: Bottom; Percent tumor cells: 99; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-50-5946-02A-01-TS1: Section location: Top; Percent tumor cells: 99; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-50-5946-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper; Pulmonary function test indicator: No.
- Follow-up form 1: Lost to follow-up: No; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: Yes.
- Follow-up form 1, New neoplasm event types: New tumor event type: Distant Metastasis.
- Follow-up form 1, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,617 days; disease-specific survival: no event (censored), 1,617 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 221 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-50-5946-01A-11D-1752-01): tumor purity 0.75, ploidy 2.63, whole-genome doublings 2.
Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-50-5946-02A-11D-2085-01): tumor purity 0.9, ploidy 2.6, whole-genome doublings 1.
